Surgical pathology report (de-identified scan), TCGA case TCGA-CD-5800, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-5800-01A (Primary Tumor).

[page 1 of 6]
Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

HISTORY OF PRESENT ILLNESS

Complaints:

Abdominal pain .

Symptoms: Patient has abdominal pain for 2 months, weight loss and fatigue

Clinical Findings: No tumor, no peripheral node was found .

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)		
				/ / To	/ /	
				/ / To	/ /	
				/ / To	/ /	
				/ / To	/ /	
				/ / To	/ /	

[page 2 of 6]
PAST MEDICAL HISTORY

Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
Healthy			

SOCIAL HISTORY

Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY

Relative	Diagnosis	Age of Diagnosis
	Nobody has cancer	

LAB DATA

Test	Result	Date	Test	Result	Date
			CEA	☐ Negative ☐ Positive: _____	
			CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☐ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	/ Normal	[REDACTED]
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Stomach Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
NO	NO	
Clinical Staging		Date of Diagnosis
T ₂ N ₀ M ₀ Stage: II		[REDACTED]

Treatment Information

SURGICAL TREATMENT			
Procedure		Date of Procedure	
Partial gastrectomy		[REDACTED]	
Primary Tumor			
Organ	Detailed Location	Size	
Stomach	Antrum	3 x x cm	
Extension of Tumor			
Serosa			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes	Perigastric	3	
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
NO			
Surgical Staging			
T ₂ N ₀ M ₀ Stage: II			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
NO				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
X	X	X	X			X	X
Time to LN2		Time to Formalin		Time to LN2			
10 min		10 min		60 min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach	3 x x cm	Serosa	3 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Perigastric	3	0	
Distant Metastasis			
Organ	Detailed Location	Size	
N0			
Pathological Staging			
pT ₃ N ₀ M ₀		Stage: II	

Notes:

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse					Streaming						
Mosaic					Storiform						
Necrosis			+		Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized			+		Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						
Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	+		Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Cellular Differentiation: Well $\nearrow$ Moderate Poor											
Nuclear Appearance											
Nuclear Atypia:						0	I	II	III		
Aniso Nucleosis								+			
Hyperchromatism								+			
Nucleolar Prominent							+				
Multinucleated Giant Cell											
Mitotic Activity								+			
Nuclear Grade:								+			

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Papillary adenocarcinoma
Grade: II

[page 6 of 6]
Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		✓	Streaming		
Mosaic	✓		Storiform		
Necrosis		✓	Fibrosis		
Lymphocytic Infiltration	✓		Palisading		
Vascular Invasion		✓	Cystic Degeneration		
Clusterized		✓	Bleeding		
Alveolar Formation		✓	Myxoid Change		
Indian File		✓	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	✓		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	✓		Fibroblast			Small Cell		
Keratin			Secretion	✓		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	✓		Lipoblast			Inflam. Cell		
Pearl			Gland formation	✓		Myoblast			Plasma Cell		
Otherwise Specified: by 40% D230% D325% D440%											

2. Cellular Differentiation:

Well	Moderately	Poor
✓		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism		✓	✓	
Nucleolar Prominent			✓	
Multinucleated Giant Cell		✓		
Mitotic Activity		✓		
Nuclear Grade				

Histological Diagnosis: *Papillary Adenocarcinoma G-1*

Source: NCI Genomic Data Commons file 67d644ff-7a65-4024-a674-f891841fe657 (TCGA-CD-5800.D807F051-89C8-4899-9747-0B9F623CD06E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).